Surgical pathology report (de-identified scan), TCGA case TCGA-XM-A8RE, project TCGA-THYM (Thymoma), tissue source site MSKCC, specimen TCGA-XM-A8RE-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account #: [REDACTED] Date of Procedure: [REDACTED]
DOB: [REDACTED] (Age: F Date of Receipt: [REDACTED]
Physician: [REDACTED] Date of Report: [REDACTED]
CC: [REDACTED]
Patient Address: [REDACTED]

....

Clinical Diagnosis & History:
History of thymoma.

Specimens Submitted:
1: Thymus (fs)

DIAGNOSIS:

1. Thymus (fs):
- Thymoma, type AB (see note)
- Tumor size: 5.0 cm.
- No capsular invasion identified
- Surgical margins are negative for tumor
- No lymphovascular invasion identified

Note: The tumor is composed of approximately 85% type B1 and 15% type A components. Immunohistochemical staining for pan-cytokeratin AE1/AE3 highlights the neoplastic epithelial cells. CD1a and TdT highlight the background thymic T-lymphocytes.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for frozen section consultation, labeled "Thymus", and consists of an unorientated, irregular portion of yellow lobular thymus measuring 14.0 x 7.5 x 2.5 cm weighing 46.0 g. The thymus has a thin fibrous lining which is previously inked blue. Sectioning reveals a 5.0 x 4.5 x 2.3 cm white-tan, homogenous, lobular mass abutting the capsule.

** Continued on next page **

ICD-O-3
Thymoma, type AB NOS
8582/1
Site Thymus
C87.9
JTD 3/12/14

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #:

Physician:

Service:

Date of Report:

Page 2 of 2

The remaining uninvolved specimen has a yellow lobular cut surface.
Representative sections are submitted. TFS and gross photographs are taken.

Summary of sections:

M--mass (blocks 2 through 4 combined full face section of mass)

RS--representative sections

Summary of Sections:

Part 1: Thymus (fs)

Blocks	Block Designation	PCs
1	{not entered}	
6	M 6	
2	RS 2	

Special Studies:

Result	Special Stain	Comment
AE1:AE3		
TDT		
CD1A (O10)		
IMM RECGT		
NEGATIVE.		

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Thymoma
PERMANENT DIAGNOSIS: Same

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Thymoma
PERMANENT DIAGNOSIS: Same

** End of Report **

HIFAA Discrepancy		✓

Source: NCI Genomic Data Commons file b5580b0a-e5e7-4807-9c83-e0f030947911 (TCGA-XM-A8RE.F1E84952-20E9-4DAA-94F8-73630E29C325.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).